MMRF case MMRF_1497 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5c43e5c4-d371-481c-8763-542fea3f737d

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Dead; Days to death: 1,176 days (3.2 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.0 years (22,296 days); ISS stage: I; Days to last known disease status: 1,176 days (3.2 years); Days to last follow up: 1,176 days (3.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 21 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 35 days; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 172 days; Days to treatment end: 172 days.
   Treatment given: Therapeutic agents: Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 182 days; Days to treatment end: 182 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 208 days; Days to treatment end: 208 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 209 days; Days to treatment end: 209 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,176.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8 (ECOG 0): M Protein 4.58 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.409 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.14 mg/dL; Immunoglobulin G 61.9 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 1.65 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.78 mmol/L; Albumin 39 g/L; Total Protein 10.8 g/dL; Glucose 5.67 mmol/L.
- Day 207 (ECOG 1): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 6.31 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.64 µg/mL; Lactate Dehydrogenase 7.85 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 331 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 5.06 mmol/L.
- Day 308 (ECOG 1): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.493 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.573 mg/dL; Immunoglobulin G 8.95 g/L; Immunoglobulin A 0.89 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 1.1 µg/mL; Lactate Dehydrogenase 8.39 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 47 g/L; Total Protein 7.6 g/dL; Glucose 4.18 mmol/L.
- Day 431 (ECOG 0): Lactate Dehydrogenase 8 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 7.6 g/dL; Glucose 4.95 mmol/L.
- Day 573: M Protein 0.32 g/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 1.24 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 6.7 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.63 mmol/L; Albumin 48 g/L; Total Protein 8.1 g/dL; Glucose 4.62 mmol/L.

Other clinical attributes
- Day -8: Weight: 72 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1497_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_1497_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
